FM case AD16588 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/e9c1bf6b-fd25-4922-bc63-d10d45f030df

Male, 54.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; primary biopsied or resected from the penis. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
